FM case AD8442 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/089465b6-9bf6-42d4-8782-3d82ecc9d4ed

Female, 56.9 years: Adenoid cystic carcinoma (ICD-O-3 8200/3) of the breast; metastasis biopsied or resected from the connective, subcutaneous and other soft tissues. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
